CPTAC case C3L-09227 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d033c229-acc6-4272-8aa6-286e086ff328

Demographics
Sex at birth: male; Race: white; Year of birth: 1945; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Fundus of stomach; Age at diagnosis: 77.0 years (28,131 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Residual disease: RX; Days to last known disease status: -7 days; Days to last follow up: -7 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 6 cm; Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 18.

Follow-up (1 entry)
- Follow-up contact recording only the day: day -7.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-09227-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 473 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-09227-23: Section location: Fundus; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-09227-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -14 days; Method of sample procurement: Blood Draw.
